Surgical pathology report (de-identified scan), TCGA case TCGA-3U-A98E, project TCGA-MESO (Mesothelioma), tissue source site University of Chicago, specimen TCGA-3U-A98E-01A (Primary Tumor).

[page 1 of 3]
Sample #
Gender: Female
DOB:
Race: White
Report Date:
Tissue Procurement Date:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- A. Aortic adventitia; excision:
- Infiltrating malignant mesothelioma
- B. Lymph node, AP window; excision:
- Metastatic malignant mesothelioma in two of six lymph nodes (2/6)
- C. Pericardial cyst; excision:
- Pericardial cyst
- Deposit of malignant mesothelioma (4 mm) in pericardial fat
- D. Lymph node, #7; excision:
- One lymph node, no tumor (0/1)
- E. Pleura, left; pleurectomy:
- Epithelioid malignant mesothelioma, see parameters below

Thoracic Mesothelioma Pathologic Parameters
Pleura/Pericardium, Resection

MACROSCOPIC

Specimen Type: Pleural resection
Tumor Site: Left pleura and pericardium
Tumor Configuration and Size: Diffuse, with two dominant nodules, larger 9.5 x 5.5 cm and second 4.0 x 3.5 cm

MICROSCOPIC

Histologic Type: Epithelioid (epithelial) mesothelioma, tubulopapillary and deciduoid types

Tumor Extension:

Into mediastinal fat

Into pericardial fat

Mediastinal organ: Aortic adventitia

Venous/Lymphatic Invasion: Indeterminate

Margins: Cannot be assessed

*Pathologic Staging (pTNM): pT4, N2, MX

Primary Tumor (pT)

pT4: Tumor (locally advanced technically unresectable) involves any of the ipsilateral pleural surfaces, with at least 1 of the following: diffuse or multifocal invasion of soft tissues of the chest wall, any involvement of rib, invasion through the diaphragm to the peritoneum, invasion of any mediastinal organ(s), direct extension to the contralateral pleura, invasion into the spine, extension to the internal surface of the pericardium, pericardial effusion with positive cytology, invasion of the myocardium.

Regional Lymph Nodes (pN)

pN2: Metastases in the subcarinal lymph node(s) and/or the ipsilateral internal mammary or mediastinal lymph node(s)

Specify: Number examined: 7
Number involved: 2

Distant Metastasis (pM): pMX: Cannot be assessed

*Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pleural mesothelioma of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

XXX

ICD O-3
Mesothelioma, epithelioid,
malignant 905213
Site: @ Pleura NOS
C38.4
4/23/14

[page 2 of 3]
[] M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D.

Electronically Signed Out by [] M.D.

Clinical History:

The patient is a year old female with mesothelioma who undergoes left thoracotomy.

Specimens Received:

A: Aortic adven tissue
B: AP window node
C: Pericardium cyst; removal
D: #7 lymph node
E: Left pluera

Gross Description:

Received are five containers, each labeled with the patient's name and medical record number.

A. Container A is further designated "1. Aortic adven tissue." Received fresh for frozen section diagnosis is a 1.2 x 1.0 x 0.3 cm pink-tan, rubbery tissue that is entirely frozen. Frozen section diagnosis is "positive for infiltrating mesothelioma" by Dr. []. The frozen section remnant is submitted entirely in cassette A1FS.

B. Container B is further designated "2. AP window node." Received fresh and placed in formalin are four tan-brown, rubbery fragments of tissue ranging in measurement from 1.9 to 0.4 cm. The largest lymph node is bisected to reveal a homogeneous pale, white, cut surface. The specimen is submitted as follows:

B1: largest lymph node bisected
B2: four candidate lymph nodes
B3: two candidate lymph nodes
B4: remaining soft tissue

C. Container C is further designated "3. Pericardium cyst; removal." Received fresh and placed in formalin is a pink-tan cystic mass measuring 4 x 2 x 1.5 cm. The outer surface is pink and translucent with a mild amount of adipose tissue. The wall is thin and is sectioned open to reveal approximately 5 cc of clear to light, yellow fluid. There are no masses or lesions along the cyst wall and it appears to be simple unilocular cyst. The specimen is entirely submitted in cassettes C1-C3.

D. Container D is further designated "4. #7 lymph node." Received fresh and placed in formalin is a 1.8 x 1.0 x 0.5 cm pink-tan lymph node. It is bisected to reveal a brown-tan, heterogenous cut surface and the specimen is submitted in cassette D1.

E. Container E is further designated "5. Left pluera." Received fresh and placed in formalin is a 150.9 gram, 12.5 x 11.8 x 2.5 cm aggregate of pleura. The specimen arrived in multiple pieces and comes unoriented. The majority of the specimen has thin, pink-tan, translucent pleura but there are areas of tan-white thickening. The largest nodular area measures 9.5 x 5.5 x 3 cm. The volume of the specimen is 250 cc. A second fragment contains a 4 x 2 x 3.5 cm white-tan, firm to rubbery nodule. It is serially sectioned to reveal a fairly homogeneous tan-white-pink, cut surface. Sectioning of the larger nodule reveals a tan-white to focally yellow cut surface. The tumor in most areas appears delineated from the surrounding muscle and soft tissue but in other areas appears to be within the muscle. The specimen is submitted as follows:

E1-E8: multiple sections of largest nodule with surrounding soft tissue

[page 3 of 3]
E9-E12: multiple sections of the smaller nodule
E13-E15: additional representative sections of the larger nodule

XX
[] M.D.

Intraoperative Consult Diagnosis:
A1FS. "Positive for infiltrating mesothelioma" by Dr. [].

Primary Tumor Site Discrepancy	NO TX	✓

Source: NCI Genomic Data Commons file d9a4426d-b0c1-4649-86a8-b7faadb1ff24 (TCGA-3U-A98E.11FB2902-12C0-4F01-ADF1-172E8736B378.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).